Surgical pathology report (de-identified scan), TCGA case TCGA-CD-5813, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-5813-01A (Primary Tumor).

[page 1 of 6]
[REDACTED]

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the [REDACTED] **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

[REDACTED]

Clinical Information

[REDACTED]

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain, nausea, sometimes vomit

Symptoms: Weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
			CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____	//	CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____	//	CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the stomach.	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T3 N0 M0 Stage: II	

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Extended Gastrectomy		
Primary Tumor		
Organ	Detailed Location	Size
Stomach tumor	Fundus	5 x 4 x 2 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T3 N0 M0 Stage: II		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	5 x 4 x 2 cm	Fundus	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃ N ₀ M ₀		Stage: II	
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			✓		Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration			✓		Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation																			
Squamous			+	-	Adenomatous			+	-	Sarcomatous			+	-	Lymphomatous			+	-
Squamoid Cell					Glandular cell			✓		Round Cell					Large Cell				
Spindle Cell					Cell Stratification					Fibroblast					Small Cell				
Keratin					Secretion					Osteoblast					RS Cell/RS Like				
Desmosome					Intracyt. Vacuole					Lipoblast					Inflam. Cell				
Pearl					Gland formation			✓		Myoblast					Plasma Cell				

Cellular Differentiation: Well Moderate Poor X

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism			✓	
Nucleolar Prominent		✓		
Multinucleated Giant Cell		✓		
Mitotic Activity			✓	
Nuclear Grade:			✓	

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: mucoinous adenocarcinoma
(poorly differentiated) **Grade:** III

Comments:

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse				Streaming			
Mosaic				Storiform			
Necrosis		X		Fibrosis			
Lymphocytic Infiltration		X		Palisading			
Vascular Invasion				Cystic Degeneration			
Clusterized				Bleeding			
Alveolar Formation				Myxoid Change			
Indian File				Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Otherwise Specified:

D, 50% D2 50% D3 30% D4 40% Neovascularization

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				X
Hyperchromatism				X
Nucleolar Prominent				X
Multinucleated Giant Cell				X
Mitotic Activity				X
Nuclear Grade				

Histological Diagnosis:

(Mucinous) Epidermal Cell Carcinoma, G-3

Source: NCI Genomic Data Commons file 2c8253de-1a40-4b00-bdf4-9a9353c7f54d (TCGA-CD-5813.D298F789-F31C-4035-919C-A6F7AF3F53AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).